TCGA case TCGA-BP-4343 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79e469c5-c18c-4c20-aaa2-8866623229d9

Demographics
Sex at birth: male; Race: white; Age at index: 64 years; Vital status: Dead; Days to death: 1,912 days (5.2 years).

Diagnoses (5)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.3 years (23,498 days); Year of diagnosis: 2003; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Palliative; Days to treatment start: 1,534 days (4.2 years); Course number: 1; Treatment anatomic sites: Distant Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 65.2 years (23,828 days); Days to diagnosis: 330 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 68.4 years (24,965 days); Days to diagnosis: 1,467 days (4.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 68.5 years (25,028 days); Days to diagnosis: 1,530 days (4.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 69.5 years (25,374 days); Days to diagnosis: 1,876 days (5.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Day 330 (post initial treatment): Progression or recurrence: Yes.
- Day 1,467 (post initial treatment): Progression or recurrence: Yes.
- Day 1,530 (post initial treatment): Progression or recurrence: Yes.
- Day 1,876 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,912 days (5.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- Calcium: Low.
- Platelets: Normal.
- Leukocytes: Elevated.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 1.5; Shortest dimension: 0.3.
  Slide TCGA-BP-4343-01A-02-BS2: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-BP-4343-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-BP-4343-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4343-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 3: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,912 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,912 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 330 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BP-4343-01): tumor purity 0.27, ploidy 2.77, whole-genome doublings 1 (call status: legacy_call).
